Somatic mutation profile of tumor specimen C3N-01873-03 (aliquot CPT0117230006) from CPTAC case C3N-01873, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.3 years (26,044 days).
Specimen C3N-01873-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64cfb00d-f951-4a30-a8f9-deeace8cfb7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01873-31 (Blood Derived Normal), aliquot CPT0117290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f3fd526-a3cb-4077-b78f-1c5f7396cdec

The open-access MAF lists 87 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 21, 3'UTR 5, Frame Shift Del 5, RNA 4, Nonsense Mutation 3, In Frame Del 2, Intron 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 171/474 reads (36%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 105/280 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PTEN | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 69/246 reads (28%) | catalogued as rs1554898053, CM981668, COSV64289438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 65/166 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 205/492 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.039); catalogued as rs774937453, COSV53145631; called by muse, mutect2, varscan2
- ADAMTS17 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs562179593; called by muse, mutect2, varscan2
- AKAP11 | c.1381T>C p.C461R | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs748937986; called by muse, mutect2, varscan2
- ASTN2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); catalogued as rs541027268, COSV100526836; called by muse, mutect2, varscan2
- CITED1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55744420; called by muse, mutect2, varscan2
- CYP2A13 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs745929748, COSV100387017, COSV57838994; called by muse, mutect2
- DAP3 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 159/478 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs930724668; called by muse, mutect2, varscan2
- DCAF12L1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 184/488 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.164); catalogued as COSV64421421; called by muse, mutect2, varscan2
- DCAF8L2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV70552052; called by muse, mutect2, varscan2
- FCRL3 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 313/750 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as rs759823787, COSV63842428; called by muse, mutect2, varscan2
- FHOD1 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762346925, COSV50759100; called by muse, mutect2, varscan2
- FLT4 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 135/313 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.901); catalogued as rs753074837, COSV56099795; called by muse, mutect2, varscan2
- HIVEP3 | c.2666G>A p.R889H | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756035254, COSV99914396; called by muse, mutect2
- INF2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 159/385 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs542700662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRS4 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV64533409; called by muse, mutect2
- LCE2B | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 235/541 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.729); catalogued as rs149198185, COSV64227553; called by muse, mutect2, varscan2
- LCE3D | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 60/930 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs371301948, COSV64231079; called by muse, mutect2
- MAN2B2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373374480; called by muse, mutect2, varscan2
- MGAT3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as COSV100361953; called by muse, mutect2, varscan2
- NALCN | c.4633C>T p.R1545W | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1407616507, COSV51930868; called by muse, mutect2, varscan2
- NR0B1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 135/335 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM012162, CM115435; called by muse, mutect2, varscan2
- OR11L1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 178/667 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1158995031; called by muse, mutect2, varscan2
- OR5B21 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs534324656, COSV64481610; called by muse, mutect2, varscan2
- PAGR1 | c.314G>A p.W105* | Nonsense Mutation (SNP) | VAF 216/535 reads (40%) | catalogued as rs1489806478; called by muse, mutect2, varscan2
- PIEZO1 | c.2941G>C p.G981R | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs529542524, COSV99965765; called by muse, mutect2, varscan2
- POLR2B | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55271867; called by muse, mutect2, varscan2
- PPM1D | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1428872112; called by muse, mutect2, varscan2
- SCN5A | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs749864465, CM1010021, COSV61143460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SESN3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1400088899, COSV53583259; called by muse, mutect2, varscan2
- TAOK2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs751670508; called by muse, mutect2, varscan2
- TRABD | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs374922285; called by muse, mutect2, varscan2
- ANKRD30B | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ATAD2 | c.4030del p.S1344Vfs*15 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- DLG3 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- EYS | c.1892G>C p.G631A | Missense Mutation (SNP) | VAF 132/350 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG2 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLYR1 | c.1636G>C p.A546P | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INHA | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); called by muse, mutect2
- KANSL1 | c.712del p.E238Nfs*41 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- KCNH8 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NFE2L2 | c.129del p.E45Sfs*32 | Frame Shift Del (DEL) | VAF 83/260 reads (32%) | called by mutect2, pindel, varscan2
- OR5J2 | c.210T>G p.D70E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PFKP | c.338del p.N113Tfs*12 | Frame Shift Del (DEL) | VAF 49/152 reads (32%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1083_1087delinsG p.T362Kfs*10 (on ENST00000521381 / NM_181523.3; = p.T92Kfs*10 on NM_181504.4) | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | called by pindel, varscan2*
- PIK3R1 | c.1365_1373del p.F456_E458del (on ENST00000521381 / NM_181523.3; = p.F186_E188del on NM_181504.4) | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCN5A | c.4179G>T p.L1393F (on ENST00000333535 / NM_198056.3; = p.L1392F on NM_000335.5) | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TPBG | c.1156C>G p.H386D | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- UBA1 | c.1331G>A p.C444Y | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- ZFP36L2 | c.614_631del p.F205_R211delinsC | In Frame Del (DEL) | VAF 231/753 reads (31%) | called by mutect2, pindel, varscan2
- ACSF3 | c.645G>A p.T215= | Silent (SNP) | VAF 108/266 reads (41%) | catalogued as rs772996642; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC34 | c.678C>T p.D226= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs765684353; called by muse, mutect2, varscan2
- CHST7 | c.540C>T p.R180= | Silent (SNP) | VAF 119/280 reads (43%) | catalogued as COSV99333119; called by muse, mutect2, varscan2
- CHST7 | c.991C>T p.L331= | Silent (SNP) | VAF 18/315 reads (6%) | catalogued as rs762061696; called by muse, mutect2
- CRB2 | c.459G>A p.A153= | Silent (SNP) | VAF 38/317 reads (12%) | called by muse, mutect2
- DLX1 | c.375A>G p.G125= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV59395311; called by muse, mutect2, varscan2
- IGHV4-28 | c.234C>T p.Y78= | Silent (SNP) | VAF 229/807 reads (28%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.57C>T p.T19= | Silent (SNP) | VAF 149/362 reads (41%) | catalogued as rs766150364; called by muse, mutect2, varscan2
- KPRP | c.1092C>T p.G364= | Silent (SNP) | VAF 277/610 reads (45%) | catalogued as rs371632676; called by muse, mutect2, varscan2
- LRIT2 | c.120G>A p.Q40= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1272153723; called by muse, mutect2, varscan2
- NYNRIN | c.3681G>A p.P1227= | Silent (SNP) | VAF 123/338 reads (36%) | catalogued as rs767642326, COSV66845347; called by muse, mutect2, varscan2
- OR2T1 | c.900G>A p.L300= | Silent (SNP) | VAF 118/238 reads (50%) | catalogued as COSV100822338; called by muse, mutect2, varscan2
- PLXNB1 | c.2721C>G p.T907= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- PTGIR | c.432C>T p.Y144= | Silent (SNP) | VAF 142/349 reads (41%) | catalogued as rs1335279675, COSV52193851; called by muse, varscan2
- RASIP1 | c.597G>A p.V199= | Silent (SNP) | VAF 105/291 reads (36%) | called by muse, mutect2, varscan2
- SI | c.1779A>T p.G593= | Silent (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2
- SOS2 | c.333T>C p.H111= | Silent (SNP) | VAF 62/137 reads (45%) | called by muse, varscan2
- TBL3 | c.2256C>T p.G752= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs377616619; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.471G>A p.T157= | Silent (SNP) | VAF 239/513 reads (47%) | catalogued as rs367965730; called by muse, mutect2, varscan2
- ZNF618 | c.2400G>A p.P800= (on ENST00000374126 / NM_001318042.2; = p.P707= on NM_133374.2) | Silent (SNP) | VAF 60/199 reads (30%) | catalogued as rs200450990, COSV55929906; called by muse, mutect2, varscan2
- ZNF835 | c.861C>T p.F287= | Silent (SNP) | VAF 177/563 reads (31%) | catalogued as rs1240508600, COSV73379131; called by muse, mutect2, varscan2
- ANXA2P2 | n.1015G>A | RNA (SNP) | VAF 125/319 reads (39%) | called by muse, mutect2, varscan2
- GUSBP10 | n.123C>T | RNA (SNP) | VAF 93/254 reads (37%) | called by muse, mutect2, varscan2
- LPGAT1 | c.*29G>C | 3'UTR (SNP) | VAF 23/278 reads (8%) | catalogued as COSV100878086; called by muse, mutect2
- MDS2 | n.74C>T | RNA (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- MPHOSPH8 | c.*1191_*1225delinsGTTTCTTGGAACCTATACGTTGTTTTTTG | 3'UTR (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2*
- MRPL3 | c.93-175C>T | Intron (SNP) | VAF 10/176 reads (6%) | catalogued as rs1455981305; called by muse, mutect2
- MYO1H | c.*11C>T | 3'UTR (SNP) | VAF 54/174 reads (31%) | catalogued as rs765389758, COSV99949164; called by muse, mutect2, varscan2
- NPIPB1P | n.567C>T | RNA (SNP) | VAF 160/478 reads (33%) | catalogued as rs549435131; called by muse, mutect2, varscan2
- RASA4DP | chr7:102678546 C>T | 3'Flank (SNP) | VAF 21/200 reads (11%) | catalogued as rs2522887; called by muse, mutect2, varscan2
- SHH | c.*41G>A | 3'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs544188816; called by muse, mutect2, varscan2
- TESPA1 | c.207-89G>T | Intron (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- ZNF646 | c.*1169C>T | 3'UTR (SNP) | VAF 48/184 reads (26%) | catalogued as rs1194088031; called by muse, mutect2, varscan2
